CPTAC case C3N-01077 — Kidney — Adenomas and Adenocarcinomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Adenomas and Adenocarcinomas; Primary site: Kidney.
https://portal.gdc.cancer.gov/cases/70cbdd42-987d-4bae-916a-dff62013351a

Demographics
Sex at birth: male; Race: white; Year of birth: 1956; Country of birth: Ukraine.

Diagnoses (1)
1. Renal cell carcinoma, NOS: ICD-O-3 morphology code: 8312/3; Tissue or organ of origin: Kidney, NOS; Site of resection or biopsy: Kidney, NOS; Tumor grade: G3; Residual disease: R0.
   Pathology details: Tumor largest dimension diameter: 4 cm.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3N-01077-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen; Freezing method: LN2; Initial weight: 1,860 mg; Time between clamping and freezing: 16 minutes; Time between excision and freezing: 14 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3N-01077-23: Section location: Kidney; Percent tumor nuclei: 85; Percent necrosis: 5.
- Sample C3N-01077-06: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen; Freezing method: LN2; Initial weight: 2,470 mg; Time between clamping and freezing: 16 minutes; Time between excision and freezing: 14 minutes; Method of sample procurement: Surgical Resection; Diagnosis pathologically confirmed: Yes.
- Sample C3N-01077-71: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Method of sample procurement: Blood Draw.
